Surgical pathology report (de-identified scan), TCGA case TCGA-77-8131, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-8131-01A (Primary Tumor).

[page 1 of 2]
Collected [REDACTED]

Histopathology Report

LEFT LOWER LOBE

Clinical Notes:

Wedge resection L lower lobe.

[REDACTED] year old man.

Weight loss of 10 kilograms.

Productive cough.

Ex-smoker.

Macroscopy:

Specimen is labelled "wedge resection L lower lobe" and consists of a piece of lung measuring 65 x 70 x 63 mm in the inflated state. The pleural surface appears normal. Sectioning the specimen reveals a cream coloured well circumscribed mass measuring 32 mm in maximal dimension. It is located at least 10 mm from the wedge resection margin. The mass abuts the pleura but does not definitely invade it. The adjacent lung shows some subpleural fibrosis and cyst formation. [RS of tumour, 1A-1D; sections of cyst formation and probable fibrosis, E and F]. [REDACTED]

Microscopy:

Sections show a well-differentiated to moderately-differentiated keratinising squamous cell carcinoma. There is extensive central necrosis, probably as a result of arterial invasion which is evident in several large pulmonary artery branches. Tumour abuts, but does not invade, the pleura. Foci suspicious for lymphatic permeation are noted. Resection margins are well clear of malignancy. No lymph nodes are included.

Sections of the adjacent lung tissue show a temporally and spatially heterogeneous inflammatory and fibrosing process located in subpleural parenchyma only. Here there is established honeycombing together with foci of interstitial lymphocytic infiltration and fibrous widening of alveolar septa. Fibroblastic foci are identified and there is some smooth muscle proliferation. There is no evidence of overlying pleuritis. A focus of organising pneumonia is noted in a more central parenchymal area.

Conclusion:

Wedge resection from left lower lobe:

- 1: Squamous cell carcinoma, 32 mm in diameter, with pulmonary arterial invasion and probable lymphatic permeation, pathological stage T2NX.
- 2: Parenchymal lung changes of usual interstitial pneumonitis (UIP).

Reported by [REDACTED]
Anatomical Pathologist
[REDACTED]

[page 2 of 2]
Collected

Histopathology Report

Copies:

Lung Cancer Registry

Source: NCI Genomic Data Commons file 508b4593-1525-453c-b78b-12e86782f3c0 (TCGA-77-8131.AAEEA1BD-8A50-444B-82D1-74347A5BC304.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).